Somatic mutation profile of tumor specimen TARGET-30-PASPXU-01A (aliquot TARGET-30-PASPXU-01A-01D) from TARGET case TARGET-30-PASPXU, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 14.4 years (5,254 days).
Specimen TARGET-30-PASPXU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34272bf8-c9df-4e6b-accb-25c6b2c92074.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASPXU-10A (Blood Derived Normal), aliquot TARGET-30-PASPXU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e95a1a05-dd0c-48dc-a0d8-5602ada8ffb7

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Missense Mutation 1, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAX | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 34/102 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52414939; called by muse, varscan2
- LLGL1 | c.2247A>T p.S749= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV57501625; called by muse, mutect2, varscan2
- COL1A1 | c.3531+25C>T | Intron (SNP) | VAF 12/99 reads (12%) | called by muse, mutect2, varscan2
- LIN28B | c.*1556G>T | 3'UTR (SNP) | VAF 13/263 reads (5%) | called by muse, mutect2
